FM case AD13195 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Bronchus and lung.
https://portal.gdc.cancer.gov/cases/9993853c-acda-4812-bfdb-59f1112917ae

Male, 54.1 years: Large cell neuroendocrine carcinoma (ICD-O-3 8013/3) of the lung; primary biopsied or resected from the lung. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
